Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5088, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5088-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, LAPAROSCOPIC RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL TYPE, WITH FOCAL ONCOCYTIC AND PAPILLARY FEATURES.
- B. FUHRMAN'S NUCLEAR GRADE IS III OF IV.
- C. RENAL CELL CARCINOMA GROWS IN PAPILLARY AND ACINAR PATTERN OF GROWTH.
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 5.1 CM.
- E. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- G. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY REVEALS SCLEROTIC GLOMERULI, PREDOMINANTLY ADJACENT TO THE TUMOR.
- J. THE ADRENAL GLAND IS NOT SUBMITTED.
- K. NO LYMPH NODE IS SEEN.
- L. TNM STAGE: pT1b Nx Mx.
- M. TNM HISTOLOGIC GRADE = G2.

Source: NCI Genomic Data Commons file 08a0a9e5-5195-440f-9931-e77d4c938df8 (TCGA-B0-5088.4E83B05C-DEA7-4F21-B2F3-8E49DC73EB6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).